Surgical pathology report (de-identified scan), TCGA case TCGA-D1-A16S, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site Mayo Clinic, specimen TCGA-D1-A16S-01A (Primary Tumor).

[page 1 of 4]
100-0-3
Carcinoma, Serous, NOS

8441/3 12/19/10
lw

Site Code Endometrium (54.1)

Surgical Pathology

SLIDE DISPOSITION:

DIAGNOSIS:

- A. Uterus, bilateral ovaries, and fallopian tubes;
hysterectomy
and bilateral salpingo-oophorectomy: FIGO grade 3 (of 3)
endometrial carcinoma, serous type, circumferentially
involving the
endometrial cavity from cervix to upper uterine fundus and
forming a
necrotic, friable, and exophytic mass (6.4 x 6.2 x 2.8
cm). The
tumor invades completely through the myometrium to uterine
serosal
soft tissues (1.7 cm of total myometrial thickness of 1.7
cm). The
tumor involves cervix/ endocervix. Lymphovascular space
invasion is
not identified. The margins are negative for tumor.
Multiple (2)
intramural leiomyomata (each 1.5 cm in greatest
dimension).
- B. Lymph nodes, left pelvic, lymphadenectomy: One (of
20) left
pelvic lymph node is positive for a microscopic focus of
metastatic
serous carcinoma.
- C. Lymph nodes, right pelvic, lymphadenectomy: Multiple
(15) right
pelvic lymph nodes are negative for tumor.
- F. Lymph nodes, right para-aortic, lymphadenectomy:
Multiple (9)
right para-aortic lymph nodes are negative for tumor.
- G. Lymph nodes, left para-aortic, lymphadenectomy:
Multiple (11)
left para-aortic lymph nodes are negative for tumor.
- D. Omentum, omentectomy: Negative for tumor.
- E. Appendix, appendectomy: Benign appendix.
- H. Diaphragm, right, biopsy: Negative for tumor.

[page 2 of 4]
With available surgical material [AJCC pT3aN1] (7th edition, 2010).

This final pathology report is based on the gross/macroscopic examination and the frozen section histologic evaluation of the specimen(s). Hematoxylin and Eosin (H&E) permanent sections are reviewed to confirm these findings. Any substantive changes identified on permanent section review will be reflected in a revised report.

GROSS DESCRIPTION:

- A. Received fresh labeled "uterus, bilateral fallopian tubes and ovaries" is a 165.0 gram uterus with attached bilateral tubes and ovaries. The uterine serosa is smooth. There is a 6.4 x 6.2 x 2.8 cm exophytic friable mass filling the endometrial cavity grossly invading 1.7 cm. The myometrial thickness is 1.7 cm. There are 2 leiomyomata, averaging 1.5 cm in greatest dimension. There is a 2.5 x 1.9 x 0.7 cm right ovary with a smooth outer surface and a solid cut surface with a 9.4 x 0.4 cm right fallopian tube which has multiple paratubal cysts. There is a 2.1 x 1.3 x 1.2 cm left ovary with a smooth outer surface which is unremarkable and a solid cut surface. Representative sections are submitted.
- B. Received fresh labeled "left pelvic nodes" is a 9.0 x 4.0 x 1.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.
- C. Received fresh labeled "right pelvic nodes" is a 10.0 x 6.5 x

[page 3 of 4]
0.5 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

D. Received fresh labeled "omentum" is a 53.0 x 5.5 x 1.0 cm portion of omentum. No masses are identified grossly. One possible lymph node is identified. Representative sections are submitted.

E. Received fresh labeled "appendix" is a 7.0 x 0.6 cm appendix with smooth serosa. There is no gross perforation. The lumen contains no fecolith. Representative sections submitted.

F. Received fresh labeled "right para-aortic nodes" is a 15.5 x 1.4 x 0.3 cm cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

G. Received fresh labeled "left para-aortic nodes" is a 4.0 x 4.0 x 2.0 cm aggregate of adipose and lymphatic tissue. Lymph nodes submitted.

H. Received fresh labeled "right diaphragm biopsy" is a 0.4 x 0.3 x 0.3 cm portion of red-tan soft tissue. All submitted.

BLOCK SUMMARY:

Part A: Uterus, bilateral fallopian tubes and ovaries

- 1 Endomyomet full thickness
- 2 Cervix 6:00
- 3 Post lower uterine segment
- 4 Right ovary
- 5 Right fallopian tube
- 6 Left ovary
- 7 Left fallopian tube

Part B: Left Pelvic Lymph Nodes

- 1 Lt pelvic LN 3(B7)
- 2 Lt pelvic LN 1(B8)
- 3 Left pelvic LN 5(B1)

[page 4 of 4]
- 4 Left pelvic LN 4(B2)
- 5 Left pelvic LN 1(B3)
- 6 Left pelvic LN 1(B4)
- 7 Left pelvic LN 3(B5)
- 8 Left pelvic LN 1(B6)

Part C: Right pelvic nodes

- 1 Rt pelvic LN 2(C1)
- 2 Rt pelvic LN 1of2(C2)
- 3 Rt pelvic LN 2of2(C2)
- 4 Rt pelvic LN 1of2(C3)
- 5 Rt pelvic LN 2of2(C3)
- 6 Rt pelvic LN 3(C4)
- 7 Rt pelvic LN 4(C5)
- 8 Rt pelvic LN 1of4(C6)
- 9 Rt pelvic LN 2of4(C6)
- 10 Rt pelvic LN 3of4(C6)
- 11 Rt pelvic LN 4of4(C6)
- 12 Rt pelvic LN 1(C7)
- 13 Rt pelvic LN 2 (C8)
- 14 Rt pelvic LN 1of2 (C9)
- 15 Rt pelvic LN 2of2 (C9)

Part D: Omentum

- 1 Omentum 1
- 2 Omentum 2
- 3 Omental ?LN 1(D1)

Part E: Appendix

- 1 Appendix tip
- 2 Appendix body

Part F: Right Para-aortic Nodes

- 1 Rt para aortic LN 3(F1)
- 2 Rt para aortic LN 2(F2)
- 3 Rt para aortic LN 1(F3)
- 4 Rt para aortic LN 2(F4)
- 5 Rt para aortic LN 1(F5)

Part G: Left Para-aortic Nodes

- 1 Lt paraaortic LN 5 (G1)
- 2 Lt paraaortic LN 2 (G2)
- 3 Lt paraaortic LN 4 (G3)

Part H: Right Diaphragm biopsy

- 1 Rt diaphragm biopsy

H ¹ AA Discrepancy		

Source: NCI Genomic Data Commons file d79a62a7-aa79-40a2-a4ac-9ca5d7b7714e (TCGA-D1-A16S.D69D2E09-B195-4F3F-B5A1-821A87852266.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).